Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5189, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5189-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

TCGA-BP-5189

Specimens Submitted:

1: SP: Right renal tumor; partial nephrectomy

DIAGNOSIS:

1. SP: Right renal tumor; partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 4.3 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

1).The specimen is received fresh for frozen section consultation and is labeled "right renal tumor stitch marks the deep surgical margin". It consists of a 5.6 x 5.2 x 4.1 cm wedge shaped portion of kidney with a suture marking the deep margin. Also received in the same container is a 7.1 x 5.2 x 0.8 cm piece of unremarkable fibroadipose tissue. Attached to the cortical surface of the portion of rectum specimen is an adherent 4.5 x 1.2 x 1.2 cm blood clot. The margin is inked black and the specimen is serially sectioned to reveal a well-circumscribed yellow lobulated focally sclerotic and hemorrhagic cortical lesion measuring 4.3 x 4.1 x 2.1 cm. The clearance from the resection margin is 0.2 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

Summary of Sections:

Part 1: SP: Right renal tumor; partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
2	M	2
1	RS	1
4	T	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: RIGHT RENAL TUMOR (REDACTED): EPITHELIOID TUMOR, MARGIN IS CLOSE (ABOUT 0.1 CM) BUT CLEAR. (REDACTED)
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 75deb02a-e62c-4d58-a569-32230b35b073 (TCGA-BP-5189.A3F07C90-AAF1-4621-AB6D-EDAD5C03E2E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).